Somatic mutation profile of tumor specimen d8345fa1-f692-4025-bc82-bfaec6 (aliquot d8345fa1-f692-4025-bc82-bfaec6_D6) from CPTAC case 20CO001, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIA.
Specimen d8345fa1-f692-4025-bc82-bfaec6: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62503661-8fb5-432a-a5f5-83c38ef5cd6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 04143d60-42b0-477d-9e44-6ab225 (Blood Derived Normal), aliquot 04143d60-42b0-477d-9e44-6ab225_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cc1a714-828f-479b-9460-092ddec7abae

The open-access MAF lists 148 somatic variants for this specimen: 100 protein-altering or splice-affecting, 30 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 30, Intron 12, Nonsense Mutation 6, RNA 3, 5'UTR 2, Frame Shift Del 2, Splice Region 1, Splice Site 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 37/240 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 79/363 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AC011462.1 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.317); catalogued as rs375957868; called by muse, mutect2, varscan2
- ACVRL1 | c.406G>C p.G136R | Missense Mutation (SNP) | VAF 55/391 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.24); catalogued as CD971966; called by muse, mutect2, varscan2
- ADAMTS3 | c.2143G>A p.V715M | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs552175669, COSV54386405, COSV54400473; called by muse, mutect2, varscan2
- ADPRH | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as rs528878906, COSV63695715; called by muse, mutect2, varscan2
- AGAP1 | c.2227G>A p.E743K (on ENST00000304032 / NM_001037131.3; = p.E690K on NM_014914.5) | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); catalogued as rs751374821, COSV58338077; called by muse, mutect2, varscan2
- AJAP1 | c.1162C>A p.R388= | Splice Region (SNP) | VAF 26/211 reads (12%) | catalogued as COSV65452928; called by muse, varscan2
- AMY1A | c.1022G>C p.G341A | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.074); catalogued as rs1356493608, COSV100915778; called by muse, mutect2
- ANKRD52 | c.1405T>C p.Y469H | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as rs754985447; called by muse, mutect2, varscan2
- ASMT | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs748103633; called by mutect2, varscan2
- ASTN1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.065); catalogued as rs1369516870, COSV56064899, COSV56071491; called by muse, mutect2, varscan2
- BEND2 | c.1809T>G p.D603E | Missense Mutation (SNP) | VAF 38/312 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV101191859; called by muse, mutect2, varscan2
- CACNA1G | c.5960C>T p.T1987M | Missense Mutation (SNP) | VAF 47/236 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.683); catalogued as rs201565895, COSV61724519; called by muse, mutect2, varscan2
- CCDC74B | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as rs544811183; called by muse, mutect2, varscan2
- CD22 | c.1516C>T p.R506* | Nonsense Mutation (SNP) | VAF 35/217 reads (16%) | catalogued as COSV50049769; called by muse, mutect2, varscan2
- COL6A2 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 51/317 reads (16%) | SIFT tolerated (0.9); PolyPhen benign (0.068); catalogued as rs765361834; called by muse, mutect2, varscan2
- DHRS1 | c.479A>G p.N160S | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs1012258863; called by muse, mutect2, varscan2
- DNM1 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs866946278, CM1414152, COSV100360012; called by muse, mutect2, varscan2
- EHD1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 55/340 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.147); catalogued as rs145959349, COSV57734098; called by muse, mutect2, varscan2
- EXT1 | c.1263G>C p.K421N | Missense Mutation (SNP) | VAF 83/372 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV65481132; called by muse, mutect2, varscan2
- FAT4 | c.13762A>G p.R4588G | Missense Mutation (SNP) | VAF 36/254 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs777451150; called by muse, mutect2, varscan2
- GABRB2 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs140795978; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR45 | c.895G>T p.G299C | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as rs780333283, COSV51522752; called by mutect2, varscan2
- GRIN2A | c.3475C>T p.R1159C | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV58019525; called by muse, mutect2, varscan2
- HGF | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV55950930, COSV55951004; called by muse, mutect2, varscan2
- KAT6B | c.1718G>A p.R573H | Missense Mutation (SNP) | VAF 48/946 reads (5%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as rs1404119097, COSV99767678; called by muse, mutect2
- KIAA1522 | c.404G>A p.R135H (on ENST00000373480 / NM_001198972.2; = p.R194H on NM_020888.3) | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs200038924; called by muse, mutect2, varscan2
- KNDC1 | c.5131G>A p.G1711S | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.434); catalogued as rs759091302, COSV58832523; called by muse, mutect2, varscan2
- LCMT1 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs568089895, COSV101111761; called by muse, mutect2, varscan2
- MMP11 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 73/416 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs376901794; called by muse, mutect2, varscan2
- MYH6 | c.3139C>T p.R1047C | Missense Mutation (SNP) | VAF 58/314 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs755565288, CM1510986, COSV62448321; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO3A | c.4411C>T p.R1471* | Nonsense Mutation (SNP) | VAF 61/474 reads (13%) | catalogued as rs1260537975; called by muse, mutect2, varscan2
- NBEA | c.6226C>T p.R2076C | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs937383651, COSV59808082; called by muse, mutect2, varscan2
- OR51I1 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs868527198, COSV100971592; called by muse, mutect2, varscan2
- P4HTM | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 21/218 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1287824436, COSV59086832; called by muse, mutect2
- PIGO | c.1487C>G p.A496G | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV53052592; called by muse, mutect2, varscan2
- PRAMEF14 | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 72/474 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.379); catalogued as rs555251277, COSV100577267; called by muse, mutect2, varscan2
- PTPRG | c.2110G>A p.G704R | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs565961396, COSV55635567; called by muse, mutect2, varscan2
- PXDC1 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.767); catalogued as rs1283560756, COSV66661360; called by muse, mutect2
- SDK2 | c.5356C>G p.L1786V | Missense Mutation (SNP) | VAF 38/231 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV66198417; called by muse, mutect2, varscan2
- SGCZ | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs201883145, COSV66018493; called by muse, mutect2, varscan2
- SLC32A1 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 83/363 reads (23%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs142909531; called by muse, mutect2, varscan2
- SPTBN2 | c.6230C>T p.A2077V | Missense Mutation (SNP) | VAF 51/375 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs748587973; called by muse, mutect2, varscan2
- TBL3 | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs762167355, COSV60340670, COSV60341222; called by muse, mutect2, varscan2
- TDRD6 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs370082076; called by muse, mutect2, varscan2
- TEKT5 | c.1327C>G p.L443V | Missense Mutation (SNP) | VAF 96/416 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773305329; called by muse, mutect2, varscan2
- TOPBP1 | c.2021G>C p.S674T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.317); catalogued as COSV53434358; called by muse, mutect2, varscan2
- TP53 | c.629del p.N210Tfs*37 | Frame Shift Del (DEL) | VAF 159/580 reads (27%) | catalogued as CD921041, COSV52979868, COSV53339346; called by mutect2, pindel, varscan2
- TRIM67 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as rs906458176, COSV64158035; called by muse, mutect2, varscan2
- VIRMA | c.1825A>G p.M609V | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs149610823; called by muse, mutect2
- ZNF527 | c.1795C>T p.R599* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as rs199808264; called by muse, mutect2, varscan2
- ABI2 | c.956C>A p.A319D | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ADCY2 | c.3151C>A p.Q1051K | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- AKAP6 | c.2101T>C p.S701P | Missense Mutation (SNP) | VAF 60/293 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- APOA5 | c.650C>G p.A217G | Missense Mutation (SNP) | VAF 74/380 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- ASIC2 | c.1025G>A p.C342Y | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BASP1 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- BCL3 | c.1124C>G p.P375R | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- BHMT | c.385C>A p.L129I | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CHD6 | c.2294C>T p.T765I | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CHL1 | c.974T>A p.V325D (on ENST00000397491 / NM_001253387.1; = p.V341D on NM_006614.4) | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- CLIP2 | c.1903C>A p.L635M | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- CPNE3 | c.730C>A p.P244T | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- DLC1 | c.4205T>A p.I1402N (on ENST00000276297 / NM_001348081.2; = p.I965N on NM_006094.5) | Missense Mutation (SNP) | VAF 54/280 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- EPS8L2 | c.1878C>G p.Y626* | Nonsense Mutation (SNP) | VAF 18/147 reads (12%) | called by muse, mutect2, varscan2
- ETFBKMT | c.21G>C p.W7C | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAT4 | c.2344A>G p.T782A | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FLT4 | c.2125_2134delinsC p.I709_Y712delinsH | In Frame Del (DEL) | VAF 25/305 reads (8%) | called by pindel, varscan2*
- FOXO6 | c.400T>C p.S134P | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2
- FRMPD4 | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 51/222 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FSCN3 | c.1013T>G p.F338C | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- GALC | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- GNB4 | c.775C>G p.Q259E | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); called by muse, mutect2
- KCNQ4 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 85/475 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- KDM5B | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIR2DL1 | c.43T>G p.L15V | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.271); called by muse, mutect2
- KRTAP5-8 | c.146G>C p.S49T | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- LARGE2 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.159); called by muse, mutect2
- LILRA5 | c.377A>G p.E126G | Missense Mutation (SNP) | VAF 52/341 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- MAP3K1 | c.3880G>T p.E1294* | Nonsense Mutation (SNP) | VAF 28/171 reads (16%) | called by muse, mutect2, varscan2
- MMP8 | c.1284C>G p.F428L | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- MON1B | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 117/471 reads (25%) | called by muse, mutect2, varscan2
- MXRA5 | c.1261G>T p.V421L | Missense Mutation (SNP) | VAF 91/379 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.17); called by mutect2, varscan2
- NBEAL2 | c.2474-8_2479del p.X825_splice | Splice Site (DEL) | VAF 37/213 reads (17%) | called by mutect2, pindel, varscan2
- NCKAP5 | c.4561A>T p.S1521C | Missense Mutation (SNP) | VAF 41/239 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NSRP1 | c.1414T>C p.S472P | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR4K14 | c.369A>T p.R123S | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PCDHB13 | c.864G>T p.E288D | Missense Mutation (SNP) | VAF 60/336 reads (18%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.031); called by mutect2, varscan2
- POTEF | c.1196A>G p.E399G | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); called by muse, varscan2
- PTCH1 | c.2872G>A p.E958K | Missense Mutation (SNP) | VAF 18/464 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.081); called by muse, mutect2
- ROBO1 | c.2141C>G p.S714C | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- RPTN | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 86/283 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- SACS | c.1671G>T p.L557F | Missense Mutation (SNP) | VAF 64/482 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0); called by mutect2, varscan2
- SLC35A1 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC6A16 | c.1483G>C p.V495L | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.132); called by mutect2, varscan2
- SLC6A20 | c.1393G>T p.A465S | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SSTR4 | c.566C>A p.P189Q | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.174); called by mutect2, varscan2
- STEAP1B | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 75/450 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- TMEM134 | c.127del p.R43Gfs*74 | Frame Shift Del (DEL) | VAF 9/69 reads (13%) | called by mutect2, pindel*, varscan2
- ADGRE2 | c.597G>A p.P199= | Silent (SNP) | VAF 58/333 reads (17%) | catalogued as rs147866335; called by muse, mutect2, varscan2
- AKAP6 | c.4584T>A p.I1528= | Silent (SNP) | VAF 50/349 reads (14%) | called by muse, mutect2, varscan2
- ARFRP1 | c.153C>T p.S51= | Silent (SNP) | VAF 26/183 reads (14%) | catalogued as rs181865540; called by muse, mutect2, varscan2
- CHAMP1 | c.813C>T p.A271= | Silent (SNP) | VAF 21/125 reads (17%) | called by muse, mutect2, varscan2
- CREB5 | c.336C>T p.P112= (on ENST00000357727 / NM_182898.4; = p.P105= on NM_004904.3) | Silent (SNP) | VAF 21/145 reads (14%) | catalogued as rs370145745, COSV63228941; called by muse, mutect2, varscan2
- FAM155B | c.381C>T p.A127= | Silent (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- FBXO33 | c.423T>C p.V141= | Silent (SNP) | VAF 40/417 reads (10%) | called by muse, mutect2, varscan2
- FOXD4L4 | c.576C>T p.F192= | Silent (SNP) | VAF 63/1046 reads (6%) | called by muse, mutect2
- HK3 | c.1575C>T p.F525= | Silent (SNP) | VAF 50/331 reads (15%) | catalogued as rs267600567, COSV52839088, COSV52843752; called by muse, mutect2, varscan2
- HOXC13 | c.120C>T p.G40= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs1051950682; called by muse, mutect2
- IGHV4-34 | c.123G>A p.S41= | Silent (SNP) | VAF 51/348 reads (15%) | catalogued as rs747173806; called by muse, mutect2, varscan2
- JPH1 | c.537C>T p.A179= | Silent (SNP) | VAF 43/205 reads (21%) | catalogued as COSV60612265; called by muse, mutect2, varscan2
- KCNG2 | c.156C>T p.H52= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs1284808298, COSV60267421; called by muse, mutect2
- LRTM2 | c.855G>A p.P285= | Silent (SNP) | VAF 42/498 reads (8%) | catalogued as rs754181370, COSV54563541; called by muse, mutect2
- LY9 | c.1488G>A p.A496= | Silent (SNP) | VAF 40/160 reads (25%) | catalogued as rs368449231; called by muse, mutect2, varscan2
- MCM3AP | c.5001G>A p.G1667= | Silent (SNP) | VAF 32/152 reads (21%) | called by muse, mutect2, varscan2
- MRPL53 | c.57G>A p.Q19= | Silent (SNP) | VAF 25/219 reads (11%) | called by muse, mutect2, varscan2
- NALCN | c.4551C>T p.Y1517= | Silent (SNP) | VAF 20/134 reads (15%) | catalogued as rs748173874, COSV51929902; called by muse, mutect2, varscan2
- PAN2 | c.633C>T p.C211= | Silent (SNP) | VAF 17/153 reads (11%) | catalogued as rs199966708, COSV57753606; called by muse, mutect2
- ROBO1 | c.3597C>T p.S1199= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as rs373039151; called by muse, mutect2, varscan2
- SKOR2 | c.48G>A p.S16= | Silent (SNP) | VAF 58/250 reads (23%) | catalogued as rs780338384, COSV101247457; called by muse, mutect2, varscan2
- SLC45A1 | c.1380G>A p.P460= | Silent (SNP) | VAF 19/176 reads (11%) | catalogued as rs937355657, COSV57099136; called by muse, mutect2, varscan2
- SMARCA2 | c.1998C>T p.S666= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as rs765966954, COSV100570714, COSV61812664; called by muse, mutect2, varscan2
- SPATC1 | c.1692C>G p.P564= | Silent (SNP) | VAF 12/242 reads (5%) | catalogued as rs1215971200; called by muse, mutect2
- SPTBN2 | c.2295C>T p.D765= | Silent (SNP) | VAF 56/549 reads (10%) | catalogued as rs140386819; called by muse, mutect2, varscan2
- SSC4D | c.663G>A p.P221= | Silent (SNP) | VAF 34/279 reads (12%) | catalogued as rs756811945; called by muse, mutect2, varscan2
- SVEP1 | c.6432G>A p.V2144= | Silent (SNP) | VAF 85/366 reads (23%) | called by muse, mutect2, varscan2
- TFAP2B | c.1188G>A p.T396= | Silent (SNP) | VAF 54/320 reads (17%) | catalogued as COSV53828816; called by muse, mutect2, varscan2
- TTC28 | c.1926T>C p.Y642= | Silent (SNP) | VAF 69/342 reads (20%) | called by muse, mutect2, varscan2
- ZBTB46 | c.702A>G p.S234= | Silent (SNP) | VAF 37/219 reads (17%) | called by muse, mutect2, varscan2
- AC012313.8 | n.4937C>G | RNA (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- C9orf16 | c.*2C>T | 3'UTR (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- CIRBP | c.-7+482G>A | Intron (SNP) | VAF 45/272 reads (17%) | called by muse, mutect2, varscan2
- DNAH17 | c.8511+2567C>T | Intron (SNP) | VAF 21/163 reads (13%) | catalogued as rs1196260120; called by muse, mutect2, varscan2
- ERLIN2 | c.425-2107T>A | Intron (SNP) | VAF 64/517 reads (12%) | called by muse, mutect2, varscan2
- ERLIN2 | c.425-2106C>G | Intron (SNP) | VAF 66/520 reads (13%) | called by muse, mutect2, varscan2
- FOXP1 | c.1652+524C>T | Intron (SNP) | VAF 10/65 reads (15%) | catalogued as rs369492837; called by muse, mutect2, varscan2
- GPM6A | c.-23+31434T>G | Intron (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
- KCNMA1 | c.2267-40T>C | Intron (SNP) | VAF 49/287 reads (17%) | called by muse, mutect2, varscan2
- LINC01164 | n.780G>C | RNA (SNP) | VAF 50/270 reads (19%) | called by mutect2, varscan2
- NDUFS8 | c.59-16G>A | Intron (SNP) | VAF 78/576 reads (14%) | catalogued as rs533915040; called by muse, mutect2, varscan2
- PHOSPHO1 | c.-6C>T | 5'UTR (SNP) | VAF 21/146 reads (14%) | called by muse, mutect2, varscan2
- SPTB | c.6346-18T>C | Intron (SNP) | VAF 44/428 reads (10%) | catalogued as rs771050794; called by muse, mutect2, varscan2
- TTN | c.-63G>C | 5'UTR (SNP) | VAF 28/153 reads (18%) | called by muse, mutect2, varscan2
- UBTFL2 | n.164C>T | RNA (SNP) | VAF 44/296 reads (15%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+4100G>C | Intron (SNP) | VAF 33/213 reads (15%) | called by muse, mutect2, varscan2
- ZNF211 | c.91-545C>T | Intron (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- ZNF606 | c.-52+322C>T | Intron (SNP) | VAF 26/167 reads (16%) | catalogued as rs749762446; called by muse, mutect2, varscan2
